Surgical pathology report (de-identified scan), TCGA case TCGA-G3-AAV7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-AAV7-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected
Time Reported
Order Number
Status

Final

Time Received
Time Transmitted
Ordering Provider
Relevant Information
Location

Report Patient Name:
Demographics (for verification purposes) Date of Birth:
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
Liver segment 2,3 at
Clinical Information
Hep B. Liver tumor. Hepatocellular carcinoma.

ICD O-3
Carcinoma, hepatocellular 8170/3
Site: Liver C22.0
JW 5/20/14

Diagnosis

- A. Liver segment 2,3, Wedge Resection:
- Moderately differentiated hepatocellular carcinoma
- (please see synoptic report for details);
- Lymphovascular invasion noted in small vessels;
- Tumor present less than 1 mm from hepatic capsule;
- Resection margin negative (more than 1 cm).

Reported by:

Electronically signed by:

Verified:

Responsible Resident:

(Resident)

Synoptic Report

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 10.0 mm

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis (Fibrosis Score: Ishak score 5 (marked bridging (portal to portal and portal to central) with occasional nodules))

*Hepatitis (specify type): Hepatitis B (Chronic Hepatitis: Grade 2 (mild periportal inflammation and piecemeal necrosis or focal hepatocellular necrosis))

[page 2 of 2]
Mild steatosis (<5% of total liver parenchyma)

Gross Description

Received is a single specimen container. The requisition and specimen container are labelled with the patient's name, The cassette and identifiers are labelled with the Surgical Number

The specimen is received fresh and is subsequently placed into formalin. The container is designated "Liver segment 2, 3". Specimen consists of a liver segment that weights 169.3 g and measures 15.0 x 7.5 x 4.0 cm. Serial sections through the liver reveals a well circumscribed yellow mass beneath the liver capsule, that measures 2.7 x 2.3 x 2.1 cm. The mass is solid, with focal areas of necrosis and punctate hemorrhage. The mass lies just beneath the liver capsule. The remainder of the liver is deep yellow in color and grossly nodular. The surgical resection margin has been painted blue and the liver capsule adjacent to the mass has been painted green. There is a defect in the capsule of the liver 2.0 cm away from the mass that has been painted yellow. The mass lies more than 1.0 cm from the surgical resection margin. Sections are submitted as follows:

- A1 to 10. the liver mass in toto
- A11. the closest surgical resection margin
- A12. uninvolved liver parenchyma
- A13. sample of the previously described defect

Microscopic Description

Sections show a well circumscribed moderately differentiated hepatocellular carcinoma with pushing borders. The carcinoma has a trabecular pattern >4 cells thick with notable areas of pseudoglandular architecture with pleomorphic hyperchromatic foci. The morphology suggests a mixed hepatocellular-cholangiocarcinoma with stem cell features. However, the immunoprofile failed to support this diagnosis.

The tumor is diffusely and strongly positive for glypican-3 indicating hepatocellular origin. It shows patchy moderate positivity alpha-1 antitrypsin, very focal mild HepPar1. Other markers of hepatocellular differentiation (alpha fetoprotein, polyclonal CEA, cytoplasmic TTF-1, BHCg and OCT3/4) are largely negative.

Markers of cholangiocytic differentiation (CK7, CK19 and polyclonal CEA). There is however, patchy strong staining for EMA.

Stem cell features are only supported by focal positivity for CD56 while CD19 and C-KIT are negative. This does not support the presence of any stem cell component.

CD30 is negative.

Tumor block = A9; Non tumor block = A12

Pathologist Comment

Dr. reviewed this case and rendered his expert opinion.

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 0a59d9ad-454a-408d-85a4-f28044ecf73f (TCGA-G3-AAV7.0F368084-04F6-4DCE-9ADF-6B3B94D274AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).